Somatic mutation profile of tumor specimen TARGET-30-PATXDV-01A (aliquot TARGET-30-PATXDV-01A-01D) from TARGET case TARGET-30-PATXDV, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Renal pelvis; Age at diagnosis: 2.2 years (802 days).
Specimen TARGET-30-PATXDV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b283c65-b1d5-4210-957b-024a811e9589.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATXDV-10A (Blood Derived Normal), aliquot TARGET-30-PATXDV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f015a1e0-26a6-4195-93d8-f32e2026c629

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Splice Site 1, Missense Mutation 1, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CUL9 | c.2181-1G>T p.X727_splice | Splice Site (SNP) | VAF 9/45 reads (20%) | catalogued as COSV52736524; called by muse, mutect2, varscan2
- TNC | c.1700G>T p.C567F | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60792193; called by muse, mutect2, varscan2
- MLLT6 | c.3009G>C p.P1003= | Silent (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- COL5A3 | c.*390C>A | 3'UTR (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
